Somatic mutation profile of tumor specimen TCGA-29-1768-01A (aliquot TCGA-29-1768-01A-01W-0633-09) from TCGA case TCGA-29-1768, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.4 years (18,396 days).
Specimen TCGA-29-1768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e292db1e-4bf4-4436-a48b-623d8674b62b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1768-10A (Blood Derived Normal), aliquot TCGA-29-1768-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/849bca6e-d56c-4a18-aa21-baa0452bb672

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, 3'UTR 1, RNA 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.882del p.D295Tfs*3 | Frame Shift Del (DEL) | VAF 64/187 reads (34%) | catalogued as rs80357587; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.2509A>T p.K837* (on ENST00000547588 / NM_001122772.2; = p.K501* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs1555198423, COSV57732590; called by muse, mutect2, varscan2
- ATP8B4 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99467837; called by muse, mutect2
- BCORL1 | c.300C>G p.D100E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV54408808; called by muse, mutect2, varscan2
- C19orf18 | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58708239; called by muse, mutect2, varscan2
- CCNB1IP1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.176); catalogued as COSV100738669; called by muse, mutect2
- DMXL2 | c.8912T>G p.L2971W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51857457; called by muse, mutect2, varscan2
- DNAH7 | c.4286C>A p.T1429K | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462272504, COSV56789177; called by muse, mutect2, varscan2
- DPP8 | c.1684G>T p.E562* (on ENST00000341861 / NM_001320875.2; = p.E546* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV55683847; called by muse, mutect2, varscan2
- DYSF | c.6143T>G p.I2048S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV50626383; called by muse, mutect2, varscan2
- EPB41 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV58054983; called by muse, mutect2, varscan2
- GCNT3 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV68532634; called by muse, mutect2, varscan2
- GGT5 | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 19/69 reads (28%) | catalogued as COSV54072844; called by muse, mutect2, varscan2
- KLHL31 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63882498; called by muse, mutect2, varscan2
- LRCH1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV60854043; called by muse, mutect2, varscan2
- MELK | c.1318_1319del p.M440Vfs*3 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as rs778108102; called by mutect2, pindel, varscan2
- MYO16 | c.1935G>C p.L645F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV51820921; called by muse, mutect2, varscan2
- NEK2 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100878791; called by muse, mutect2
- NELFA | c.1385T>A p.V462D (on ENST00000542778; = p.V451D on NM_005663.5) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56397297; called by muse, mutect2, varscan2
- NFXL1 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV61201011; called by muse, mutect2, varscan2
- OR8K3 | c.488T>A p.I163N | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV57133326; called by muse, mutect2, varscan2
- PCNX1 | c.1667C>A p.A556D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV99457520; called by muse, mutect2
- PI15 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52643531, COSV99478269; called by muse, mutect2
- PLAA | c.1829T>C p.V610A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV68305701; called by muse, mutect2, varscan2
- PSMC1 | c.58-1G>A p.X20_splice | Splice Site (SNP) | VAF 66/150 reads (44%) | catalogued as COSV54322280; called by muse, mutect2, varscan2
- SMARCA1 | c.1860C>G p.F620L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV64414071; called by muse, mutect2, varscan2
- SNAP23 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV51041462; called by muse, mutect2, varscan2
- TEAD2 | c.1025C>G p.T342S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.179); catalogued as COSV100115187; called by muse, mutect2
- TET2 | c.2195C>A p.P732Q | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV54403729, COSV54434998; called by muse, mutect2, varscan2
- TLR7 | c.1473C>A p.C491* | Nonsense Mutation (SNP) | VAF 10/316 reads (3%) | catalogued as COSV101028177; called by muse, mutect2
- TUBGCP4 | c.361C>G p.H121D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV53021753; called by muse, mutect2, varscan2
- TXLNB | c.297T>A p.D99E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as COSV64445866; called by muse, mutect2, varscan2
- UEVLD | c.1018G>C p.G340R | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV57877220; called by muse, mutect2, varscan2
- XKR5 | c.235T>C p.W79R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746604913, COSV68398959; called by muse, varscan2
- ZBTB16 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100252239; called by muse, mutect2
- ZIC4 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101268183; called by muse, mutect2
- ZNF445 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV101253911; called by muse, mutect2
- ADAMTS1 | c.1221dup p.N408* | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by pindel, varscan2
- PTS | c.203_208del p.G68_M69del | In Frame Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- RYK | c.914_944del p.R305Lfs*9 (on ENST00000620660 / NM_001005861.2; = p.R302Lfs*9 on NM_002958.4) | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- TTC1 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC004922.1 | c.1287G>T p.R429= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV53165062; called by muse, mutect2
- EQTN | c.279T>A p.A93= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV66218474; called by muse, mutect2, varscan2
- NIM1K | c.360A>C p.R120= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as COSV58146557; called by muse, mutect2, varscan2
- OR5D14 | c.126A>G p.V42= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV59458978; called by muse, mutect2, varscan2
- PEAK1 | c.3897G>A p.K1299= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV56944238; called by muse, mutect2, varscan2
- RGS2 | c.306G>A p.K102= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV52459866; called by muse, mutect2, varscan2
- SEC16B | c.2019C>A p.I673= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV57623608, COSV57630519; called by muse, mutect2, varscan2
- SLC30A7 | c.138C>G p.L46= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100725620; called by muse, mutect2, varscan2
- ZSWIM8 | c.2154A>C p.A718= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV101290174; called by muse, mutect2
- DCHS2 | n.3260G>C | RNA (SNP) | VAF 71/223 reads (32%) | catalogued as COSV59740692; called by muse, mutect2, varscan2
- LEKR1 | c.*1360G>C | 3'UTR (SNP) | VAF 24/67 reads (36%) | catalogued as COSV62965113; called by muse, mutect2, varscan2
